Somatic mutation profile of tumor specimen TARGET-40-PAMTCM-01A (aliquot TARGET-40-PAMTCM-01A-01D) from TARGET case TARGET-40-PAMTCM, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.5 years (4,938 days).
Specimen TARGET-40-PAMTCM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 927240ac-148d-4c86-8685-8f9430781359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMTCM-10A (Blood Derived Normal), aliquot TARGET-40-PAMTCM-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8576aa4f-60d7-487c-9b24-cf7bf9755212

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, 3'UTR 2, Nonsense Mutation 2, 5'UTR 2, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC1 | c.2917C>T p.R973* | Nonsense Mutation (SNP) | VAF 41/115 reads (36%) | catalogued as rs749980467, COSV61756452, COSV61758671; called by muse, mutect2, varscan2
- CLPB | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV53627418; called by muse, mutect2
- COL1A1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as rs1203507565; called by mutect2, varscan2
- DCAF4L1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs143365042; called by muse, mutect2, varscan2
- DIRAS3 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1240516232, COSV63970681; called by muse, mutect2, varscan2
- NTN3 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1275747409, COSV53546540; called by mutect2, varscan2
- OPN1LW | c.834C>G p.C278W | Missense Mutation (SNP) | VAF 137/219 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64049275; called by muse, mutect2, varscan2
- OR2T34 | c.520del p.C174Afs*7 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV100170523; called by mutect2, varscan2
- ADGB | c.766_767insC p.D256Afs*42 | Frame Shift Ins (INS) | VAF 23/65 reads (35%) | called by mutect2, pindel*, varscan2
- C2CD2 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); called by muse, varscan2
- CLEC17A | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- HHIPL1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MPL | c.1747T>C p.C583R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OR2T10 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PYHIN1 | c.1360A>T p.K454* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- SPC24 | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- STBD1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TFE3 | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ZNF410 | c.581-7G>T | Splice Region (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- OR1L6 | c.822C>T p.A274= (on ENST00000373684; = p.A238= on NM_001004453.2) | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2
- PKHD1 | c.8754C>T p.G2918= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- SYNE3 | c.888G>A p.E296= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs1297804486; called by muse, mutect2, varscan2
- TFAP2B | c.405T>C p.L135= | Silent (SNP) | VAF 8/13 reads (62%) | called by mutect2, varscan2
- ACTBL2 | c.-9G>T | 5'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- AMPH | c.1182+577C>A | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100343673; called by muse, mutect2, varscan2
- CYP4F2 | c.397+44G>A | Intron (SNP) | VAF 62/77 reads (81%) | catalogued as rs902933201, COSV50002955; called by muse, mutect2, varscan2
- NDST2 | c.*29C>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- PTGFRN | c.*1G>A | 3'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101277216; called by muse, mutect2, varscan2
- USP17L2 | c.-91T>C | 5'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as rs748652021, COSV61556922; called by mutect2, varscan2
